TARGET case TARGET-20-HEK293 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/48431b62-774d-48c8-aee6-8022b44fe801

Biospecimens (1 sample)
- Sample TARGET-20-HEK293-50A: Sample type: Cell Lines; Tissue type: Tumor; Specimen type: Derived Cell Line.
